Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7045, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7045-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Other Related Data:

Billing Type:

Financial Number:

Clinical Diagnosis & History:

Left renal mass; chronic renal insufficiency; proteinuria.

Specimens Submitted:

1: SP: Lt. kidney

2: SP: Portion of left 11th rib

3: SP: Hilar lymph node left

DIAGNOSIS:

1. KIDNEY, LEFT; NEPHRECTOMY:

- PAPILLARY RENAL CELL CARCINOMA.
- THE TUMOR'S GREATEST DIAMETER IS 4.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.

- THE NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL NEPHRITIS, ARTERIOLECTEROSIS, BENIGN CORTICAL CYSTS, AND ON CONVENTIONAL H&E STAINED SECTIONS, WE FIND FOCAL GLOMERULAR HYPERTROPHY, SEGMENTAL SCLEROSIS, AND FOCALLY MARKED THICKENING OF CAPILLARY WALLS. NO MALIGNANT OR ENDOCAPILLARY PROLIFERATION IS PRESENT.

- RESULTS OF ELECTRON MICROSCOPY, IMMUNOFLOUORESCENCE, AND SPECIAL STAINS WILL BE REPORTED IN A CONSULTATION FROM US.

2. ELEVENTH RIB; PARTIAL EXCISION:

- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT MICROSCOPIC ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.

3. LYMPH NODE, LEFT HILAR; EXCISION:

- MULTIPLE BENIGN LYMPH NODES.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 3]
Gross Description:

1) The specimen is received fresh, labeled "Left Kidney". It consists of a left kidney with attached perinephric fat measuring 14.0 x 10.7 x 7.0 cm overall. The kidney proper measures 11.0 x 7.0 x 6.5 cm. A large tumor bulges from the superior pole. The ureteral stump is unremarkable and measures 5.0 cm in length and 0.7 cm in circumference. The vascular margin is also unremarkable as well. The kidney is bisected to reveal a single 5.0 x 5.0 x 4.0 cm mass with well-circumscribed borders. Cut surfaces are variegated, pale yellow admixed with hemorrhage. The tumor does not involve the pelvicalyceal system which is lined by pale gray mucosa. The tumor attenuates the capsule but does not breach it. The uninvolved kidney shows numerous cortical cysts, ranging up to 1.2 cm in greatest dimension, all with a smooth lining and filled with serous fluid. The uninvolved renal parenchyma is light brown-red. The specimen is representatively submitted. A portion of non-neoplastic kidney is fixed in glutaraldehyde for EM studies. A portion is also frozen for possible immunofluorescence. The tumor is saved for EM and _____ as well.

Summary of Sections:

UM - ureteral margin

VM - vascular margin

T - tumor

N - non-neoplastic kidney

2) The specimen is received in formalin, labeled "Portion of left eleventh rib". It consists of a portion of rib, measuring 4.2 x 1.0 x 0.4 cm. Representative sections are submitted.

Summary of Sections:

D - Distal

3) The specimen is received in formalin, labeled "Hilar lymph nodes, left". It consists of an irregular piece of yellow-tan, firm adipose tissue, measuring 2.0 x 1.7 x 0.5 cm, possibly containing lymph nodes. The specimen is bisected and submitted entirely.

Summary of Sections:

T - Undesignated

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	H		6	M	N
	T		8	M	
	UM		1	1	
	VM		1	1	
2	D		1	1	N

[page 3 of 3]
Procedures/Addenda:

Addendum

Date Ordered

Status: Signed Out

Addendum Diagnosis

THE RESULTS OF MICROSCOPIC AND ULTRASTRUCTURAL EXAMINATION OF THE NONNEOPLASTIC KIDNEY, AS REPORTED IN A CONSULTATION FROM SURYA V. SESHAN, M.D., THE NEW YORK HOSPITAL-CORNELL MEDICAL CENTER ARE AS FOLLOWS:

- FOCAL SEGMENTAL AND GLOBAL GLOMERULOSCLEROSIS, MODERATELY ADVANCED.
- CONSIDERABLE GLOMERULOMEGALY.
- FOCI OF ACUTE TUBULAR DAMAGE/NECROSIS, POSSIBLY SCHEMIC IN NATURE.
- FAIRLY EXTENSIVE TUBULAR ATROPHY WITH INTERSTITIAL FIBROSIS AND CHRONIC INFLAMMATORY INFILTRATE.
- ARTERIO- AND ARTERIOVENOSCLEROSIS, SEVERE.

Source: NCI Genomic Data Commons file 07441414-54c8-4a2f-b083-87cc743aed43 (TCGA-BQ-7045.CCB6FC6F-4BAF-4204-AF81-48667E9A9C90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).